Somatic mutation profile of tumor specimen TARGET-10-PARCUW-09A (aliquot TARGET-10-PARCUW-09A-01D) from TARGET case TARGET-10-PARCUW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,341 days).
Specimen TARGET-10-PARCUW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 532dd3ed-b5d6-44e8-a621-681ad23ff2e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCUW-10A (Blood Derived Normal), aliquot TARGET-10-PARCUW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2ea65ce-fde0-46f1-83d9-6ed255ed7492

The open-access MAF lists 37 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Intron 6, Nonsense Mutation 6, RNA 2, Splice Site 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AZIN1 | c.809C>G p.S270* | Nonsense Mutation (SNP) | VAF 9/121 reads (7%) | catalogued as COSV61479745; called by muse, mutect2
- BECN1 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV59312461; called by muse, mutect2
- CAMK2A | c.1318G>A p.A440T (on ENST00000348628 / NM_171825.2; = p.A451T on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.228); catalogued as rs374924411; called by muse, mutect2, varscan2
- CNTNAP1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1388157342; called by muse, mutect2
- EZH1 | c.-11-1G>C | Splice Site (SNP) | VAF 5/66 reads (8%) | catalogued as COSV70549093; called by muse, mutect2
- FAM126B | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV53772917; called by muse, mutect2, varscan2
- PLXNB1 | c.4354C>T p.R1452* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as rs1237113269, COSV56491358; called by muse, mutect2, varscan2
- C2orf16 | c.3853G>A p.D1285N | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2
- DHX34 | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- DOCK1 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 57/102 reads (56%) | called by muse, mutect2, varscan2
- DST | c.11336T>G p.I3779R (on ENST00000361203 / NM_001374722.1; = p.I1367R on NM_015548.5) | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EDA2R | c.781A>T p.K261* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- MED23 | c.2524C>T p.Q842* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- MED23 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TPST1 | c.846-1G>C p.X282_splice | Splice Site (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- TTN | c.12496G>C p.E4166Q (on ENST00000591111; = p.E4120Q on NM_003319.4) | Missense Mutation (SNP) | VAF 95/217 reads (44%) | called by muse, mutect2, varscan2
- ZNF281 | c.474G>C p.E158D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2
- ZNF91 | c.2516C>G p.S839* | Nonsense Mutation (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- JPH1 | c.879C>T p.F293= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as COSV60608312; called by muse, mutect2, varscan2
- KCNJ15 | c.792G>A p.L264= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV100154097, COSV60810374; called by muse, mutect2, varscan2
- MN1 | c.2754C>G p.L918= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- NYNRIN | c.3276C>T p.T1092= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as rs371702363; called by muse, mutect2, varscan2
- OR52B2 | c.210C>T p.V70= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs753558772; called by muse, mutect2, varscan2
- ROS1 | c.1602G>C p.L534= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- SPECC1 | c.171C>T p.D57= | Silent (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- ZFP91 | c.1281C>T p.F427= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- CORO1C | c.-2C>T | 5'UTR (SNP) | VAF 21/131 reads (16%) | catalogued as rs768486704, COSV54599633; called by muse, mutect2, varscan2
- CSH1 | c.457-124C>T | Intron (SNP) | VAF 18/60 reads (30%) | catalogued as rs945517620, COSV60241939, COSV60242986; called by muse, mutect2, varscan2
- DENND4B | c.640+99C>G | Intron (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- EIF3F | c.364+125del | Intron (DEL) | VAF 9/19 reads (47%) | called by mutect2, varscan2
- EIF3IP1 | n.717T>G | RNA (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- JMJD4 | c.693-82C>T | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3350+2008C>G | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- LRFN5 | c.*43G>A | 3'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- NOC2LP1 | n.1406C>T | RNA (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- RUNDC3A | c.1199-586C>G | Intron (SNP) | VAF 33/81 reads (41%) | catalogued as rs1427594975; called by muse, mutect2, varscan2
